Gene-level copy-number profile of tumor specimen MP2PRT-PAPBAX-TMP1-A from MP2PRT case MP2PRT-PAPBAX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (710 days).
Specimen MP2PRT-PAPBAX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 794b7575-e6a3-4c16-b917-7cbb1b963544.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPBAX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/0bdef592-3db1-42e3-b7b7-45a3f36d010d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 300; copy number 2: 55,289; copy number 3: 1,150; copy number 4: 1,647; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,581,339–161,678,654, 5 genes, copy number 6 (within-gene range 3–6): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B.
- chr1:196,774,813–196,795,407, 1 gene, copy number 6: CFHR3.

Autosomal genes at a single copy (total copy number 1): 300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
